Somatic mutation profile of tumor specimen 0DUIYO from CCDI case PBCLIY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Spinal cord; Age at diagnosis: 16.0 years (5,851 days).
Specimen 0DUIYO: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 62aea97f-42f0-49b6-b79f-7adfb18e0ec0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUIWR (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/81694529-8414-412a-bf4c-922b7d4c3c2f

The open-access MAF lists 10 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 2, Silent 1, Nonsense Mutation 1, Translation Start Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DLGAP2 | c.349C>T p.R117W | Missense Mutation (SNP) | VAF 30/192 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs988565981, COSV70095355; called by muse, mutect2, varscan2
- NKX2-8 | c.65C>A p.A22E | Missense Mutation (SNP) | VAF 40/239 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.275); catalogued as COSV51873818; called by muse, mutect2, varscan2
- USP49 | c.1153G>T p.V385L | Missense Mutation (SNP) | VAF 46/303 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs1448694142; called by muse, mutect2, varscan2
- CYP11B1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 13/219 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- EGFR | c.1627G>T p.E543* | Nonsense Mutation (SNP) | VAF 42/891 reads (5%) | called by muse, mutect2
- SERPINB9 | c.260G>A p.R87K | Missense Mutation (SNP) | VAF 55/431 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- JMY | c.1620A>G p.V540= | Silent (SNP) | VAF 104/451 reads (23%) | catalogued as COSV101268097; called by muse, mutect2, varscan2
- FLVCR1 | c.739-85C>A | Intron (SNP) | VAF 4/26 reads (15%) | called by mutect2, varscan2
- MPHOSPH9 | c.3030-29dup | Intron (INS) | VAF 34/140 reads (24%) | catalogued as rs747591273; called by mutect2, varscan2
- SATL1 | c.-141C>A | 5'UTR (SNP) | VAF 9/216 reads (4%) | catalogued as rs1233741019; called by muse, mutect2
